Somatic mutation profile of tumor specimen 0DAWAL from CCDI case PBBJNB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (758 days).
Specimen 0DAWAL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a1aa84d-85ac-4865-baf3-e11a132e3875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAWAB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8c7d160-e36a-4b1f-9945-0c88be6d0f85

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRDM1 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 360/967 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV64846795, COSV64847067; called by muse, mutect2, varscan2
- RAD17 | c.1941G>T p.Q647H (on ENST00000380774 / NM_133339.2; = p.Q636H on NM_002873.1) | Missense Mutation (SNP) | VAF 100/1052 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- PHF20 | c.2970G>A p.K990= | Silent (SNP) | VAF 355/849 reads (42%) | called by muse, mutect2, varscan2
- ZNF280A | c.1440G>A p.P480= | Silent (SNP) | VAF 135/1892 reads (7%) | catalogued as rs765568927, COSV100131061; called by muse, mutect2
- DRAP1 | c.330-50G>A | Intron (SNP) | VAF 159/331 reads (48%) | catalogued as rs1184010655; called by muse, mutect2, varscan2
